Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5737, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5737-01A (Primary Tumor).

TCGA-CH-5737

Diagnosis

1. Predominantly poorly differentiated adenocarcinoma of the prostate on both sides with predominance in the peripheral zone and the transitional zone. Maximum tumor spread 2.4 cm. Focally perineural invasion. No identifiable extraprostatic tumor growth and no identifiable invasion of the vessels. Tumor-free seminal vesicles.
2. Fatty tissue with five tumor-free lymph nodes.
3. Five tumor-free lymph nodes.

Remark

In summary, the tumor is classified as follows:

pT2c, pN0 (0/8), L0, V0; Gleason 4+3 = 7 (approx. 60% Gleason 4).

In the region of the tissue defects, carcinoma cells extend rectolaterally on both sides to the artefactual preparation margin (yellow labeling). The other preparation margins (green and blue labeling) are tumor-free.

Source: NCI Genomic Data Commons file 64ca1a62-9494-495d-ad5b-12e61c7a8bdb (TCGA-CH-5737.DBF280BB-FB7C-422F-B772-A62381C19AFA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).